Gene-level copy-number profile of tumor specimen TARGET-40-PAKFVX-01A from TARGET case TARGET-40-PAKFVX, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.8 years (5,407 days).
Specimen TARGET-40-PAKFVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.fb1a4be5-55b5-506d-9c92-88e202e19aac.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAKFVX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 406 have no estimate.
https://portal.gdc.cancer.gov/files/c3ea41f8-ef94-4416-b651-e18f87845683

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 663; copy number 1: 2,220; copy number 2: 24,407; copy number 3: 24,281; copy number 4: 6,846; copy number 5: 961; copy number 6: 363; copy number 7: 174; copy number 8: 30; copy number 9: 7; copy number 10: 162; copy number 11: 18; copy number 17: 3; copy number 26: 18; copy number 32: 2; copy number 39: 55; copy number 48: 2; copy number 54: 5.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,418,210–158,554,405, 10 genes: OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1.
- chr7:147,080,934–147,167,572, 3 genes: CNTNAP2-AS1, DUTP3, RANP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,799 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–152,445,456, 358 genes, copy number 5 (broad region; genes not listed).
- chr2:9,757,496–10,914,225, 37 genes, copy number 5 (within-gene range 4–5): AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1, RN7SL832P, Metazoa_SRP, AC092687.2, ATP6V1C2, RNU7-138P, AC092687.3, PDIA6, RNU7-176P, LINC01954, AC092687.1, AC079587.1, KCNF1.
- chr2:11,833,926–12,702,913, 1 gene, copy number 5 (within-gene range 4–5): MIR3681HG.
- chr2:12,411,398–13,609,168, 9 genes, copy number 5: RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1.
- chr2:14,530,941–15,561,334, 7 genes, copy number 5 (within-gene range 4–5): Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18.
- chr2:15,918,350–16,555,564, 17 genes, copy number 5 (within-gene range 4–5): MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2.
- chr2:55,865,967–56,181,652, 8 genes, copy number 5 (within-gene range 4–5): EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813.
- chr2:76,747,719–90,047,057, 270 genes, copy number 5–17 (broad region; genes not listed).
- chr2:194,587,925–197,380,892, 36 genes, copy number 5–6: AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, AC068544.2, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46.
- chr2:197,404,718–197,404,854, 1 gene, copy number 5: AC010746.1.
- chr2:197,693,106–200,519,784, 28 genes, copy number 5–8: AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1, LINC01877, SEPHS1P6, FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1, KCTD18.
- chr3:175,767,558–178,385,479, 31 genes, copy number 6–7 (within-gene range 1–7): RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1.
- chr4:51,843,000–65,705,553, 184 genes, copy number 5 (broad region; genes not listed).
- chr5:21,616,262–22,853,344, 7 genes, copy number 6 (within-gene range 3–16): AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2.
- chr5:36,876,769–37,066,413, 1 gene, copy number 10 (within-gene range 4–10): NIPBL.
- chr5:37,085,056–45,228,428, 138 genes, copy number 5–11 (broad region; genes not listed).
- chr6:61,574,328–63,779,336, 23 genes, copy number 7–9: MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4.
- chr9:113,570,190–113,682,855, 4 genes, copy number 5 (within-gene range 3–5): AL162727.2, AL162727.3, AL162727.1, AL157702.2.
- chr11:1,554,051–5,678,434, 227 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:46,332,905–46,386,608, 4 genes, copy number 7 (within-gene range 3–7): DGKZ, MIR4688, MDK, CHRM4.
- chr11:46,428,653–46,451,889, 3 genes, copy number 7: AC024293.1, MIR3160-1, MIR3160-2.
- chr12:10,699,089–11,590,369, 45 genes, copy number 7: YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252.
- chr15:19,878,555–23,407,335, 167 genes, copy number 5 (broad region; genes not listed).
- chr15:50,798,670–50,908,603, 2 genes, copy number 6 (within-gene range 4–6): AC012100.1, AC021752.1.
- chr16:85,282,958–85,352,961, 3 genes, copy number 6: LINC00311, MIR5093, AC092377.1.
- chr18:47,390–5,004,537, 101 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:27,638,483–32,072,113, 82 genes, copy number 26–54 (within-gene range 2–54) (broad region; genes not listed).
- chr19:33,555,568–33,589,688, 2 genes, copy number 6: AC010485.1, RPL21P131.

Autosomal genes at a single copy (total copy number 1): 533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
